Somatic mutation profile of tumor specimen MP2PRT-PASRME-TMP1-A (aliquot MP2PRT-PASRME-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASRME, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,900 days).
Specimen MP2PRT-PASRME-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76ce28b4-3035-48c1-b609-e240fab8ee95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASRME-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASRME-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b76211aa-614a-4730-8bd5-33f1f4895157

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 14, Silent 4, Nonsense Mutation 2, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FIBCD1 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 42/367 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as rs761248009; called by muse, mutect2
- FTMT | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 48/636 reads (8%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs570905707, COSV58420160; called by muse, mutect2
- MASP1 | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 134/300 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as rs775254504, COSV61826645; called by muse, mutect2, varscan2
- MINDY2 | c.797G>A p.C266Y | Missense Mutation (SNP) | VAF 36/410 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100376529; called by muse, mutect2
- PAK5 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 133/350 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs559966028, COSV62025299, COSV62039210; called by muse, mutect2, varscan2
- PRICKLE2 | c.805C>T p.R269* (on ENST00000295902; = p.R213* on NM_198859.4) | Nonsense Mutation (SNP) | VAF 36/370 reads (10%) | catalogued as rs753970642, COSV55767918; called by muse, mutect2
- TLL2 | c.2446C>T p.L816F | Missense Mutation (SNP) | VAF 9/231 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as rs1449117503; called by muse, mutect2
- UBA2 | c.212C>A p.S71* | Nonsense Mutation (SNP) | VAF 22/250 reads (9%) | catalogued as COSV55825733, COSV99874892; called by muse, mutect2
- ZNF654 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs943063247; called by muse, mutect2, varscan2
- CBFA2T3 | c.1018C>A p.P340T | Missense Mutation (SNP) | VAF 246/589 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- DCSTAMP | c.1342C>A p.H448N | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.069); called by muse, mutect2
- GK2 | c.419A>T p.K140M | Missense Mutation (SNP) | VAF 142/325 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- IGLV8-61 | c.352_368delinsGGGGA p.M118_I122delinsG | In Frame Del (DEL) | VAF 45/88 reads (51%) | called by pindel, varscan2*
- PRR23A | c.114A>C p.E38D | Missense Mutation (SNP) | VAF 262/564 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SPATA31D1 | c.339G>C p.Q113H | Missense Mutation (SNP) | VAF 122/382 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- UBA2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 16/282 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2
- UGT1A7 | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 42/397 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- USH2A | c.10363A>T p.S3455C | Missense Mutation (SNP) | VAF 117/265 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- CSPG4 | c.1113G>A p.L371= | Silent (SNP) | VAF 248/531 reads (47%) | called by muse, mutect2, varscan2
- NKAIN3 | c.492C>T p.A164= | Silent (SNP) | VAF 87/281 reads (31%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.5640C>G p.V1880= | Silent (SNP) | VAF 40/405 reads (10%) | called by muse, mutect2
- TTN | c.81015A>G p.E27005= (on ENST00000591111; = p.E19581= on NM_003319.4) | Silent (SNP) | VAF 127/313 reads (41%) | called by muse, mutect2, varscan2
